Surgical pathology report (de-identified scan), TCGA case TCGA-BS-A0V6, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Hawaii, specimen TCGA-BS-A0V6-01A (Primary Tumor).

[page 1 of 3]
ICD-0-3

Adenocarcinoma, Endometrioid, NOS 8380/3

Site: Endometrium C54.1 h 5/11

Surgical Pathology Report

Patient Name: [REDACTED]
Med Rec No: [REDACTED]
DOB: [REDACTED]
Gender: F
Physician(s): [REDACTED]
cc: [REDACTED]

Location: [REDACTED]
Pt. Phone no [REDACTED]

Accession #: [REDACTED]
Taken: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]

History/Clinical Dx: Endometrial adenocarcinoma, Grade 1

Postoperative Dx: Pending pathology exam

Specimen(s) Received:

- A: Uterus, cervix, bilateral tubes and ovaries
- B: Left pelvic lymph node
- C: Left aortic lymph node
- D: Right pelvic lymph node
- E: Right aortic lymph node

DIAGNOSIS:

A. Uterus, cervix, bilateral tubes and ovaries:

ENDOMETRIAL ADENOCARCINOMA

Tumor Information:

Operative procedure:	TAH-BSO with staging
Histologic type:	Endometrioid
Histologic grade(FIGO):	Grade 1
Nuclear grade:	2
Tumor size:	3.5 cm
Extent of invasion:	Less than 50% of myometrium (1mm invasion; 18mm myometrial thickness)
Lympho/vascular invasion:	Not identified
Serosa:	Free of tumor
Parametrium:	Free of tumor
Cervical involvement:	Absent
Right adnexa:	Free of tumor
Left adnexa:	Free of tumor
Other findings:	Intramural leiomyomata
Special studies:	On request
Staging information:	T1b, N0

B. Left pelvic lymph nodes:

Twelve lymph nodes negative for metastasis (0/12)

C. Left aortic lymph nodes:

Three lymph nodes negative for metastasis (0/3)

D. Right pelvic lymph nodes:

Ten lymph nodes negative for metastasis (0/10)

Procedures Statement:

The following statement may be applicable to some of the tests performed on this specimen. This test was developed and its performance characteristics determined by the laboratory. It is not intended for use in the diagnosis, prognosis, or treatment of disease. The test is used for research purposes only. The test is not intended for use in the diagnosis, prognosis, or treatment of disease. The test is used for research purposes only. The test is not intended for use in the diagnosis, prognosis, or treatment of disease. The test is used for research purposes only.

[page 2 of 3]
Surgical Pathology Report

E. Right aortic lymph nodes:

Five lymph nodes negative for metastasis (0/5)

Gross Description

- A. Received: In formalin are three pieces of unoriented, previously opened soft tan tissue
- Labeled: "cervix, uterus, bil. tubes and ovaries"
- Weight: 95.0 gms
- Size:
- Uterus: 8.6 x 6.5 x 4.0 cm
- Right ovary: 2.6 x 1.5 x 0.7 cm
- Left ovary (blue): 2.2 x 1.7 x 0.8 cm
- Appearance
- Tumor
- Location: Circumferential, body and fundus of uterus
- Size: 3.5 x 1.1 x 0.6 cm
- Appearance: Fungating, circumferential, friable, white
- Depth of invasion: Superficial, does not appear to involve more than 1/2 of the myometrium
- Invasion of contiguous structures: None identified
- Distance from margins: 3.9 cm from the cervical margin
- Cervix: Smooth, shiny, with no lesions
- Endometrium: 0.2 cm, smooth, shiny with areas of mucoid material
- Myometrium: 2.1 cm. No areas of adenomyosis identified
- Right tube and ovary: The right tube measures 5.0 x 0.8 x 0.7 cm, is grossly unremarkable, with no paratubal cystic structures identified. The right ovary cut surface is smooth, homogeneous, tan to white with no cystic structures
- Left tube and ovary (blue): Left tube is 5.7 x 0.5 x 0.4 cm, is grossly unremarkable, with no paratubal cystic structures. The left cut surface is smooth, homogeneous, white, with no cystic structures
- Lymph nodes: None identified
- Special studies: Pending
- Other: 3 well-circumscribed, white with whorled cut surface myomas, largest up to 1.7 x 1.5 x 1.1 cm.

KEY TO CASSETTES:

- A1 - Cervix
- A2 - Lower uterine segment
- A3-A12 - endomyometrium, with tumor in A6, A7, and A8
- A13 - Right and left parametrium (right inked black, left inked blue)
- A14 - Representative of myomas
- A15 - Right and left adnexa (left adnexa inked blue)

- B. Received in formalin labeled [redacted] left pelvic lymph node" is a fragment of yellow-tan fatty soft tissue, 10.0 grams, 4.0 x 3.0 x 2.0 cm. By palpation, there are multiple distinct nodes, pink-tan in color, 2.5 cm in greatest dimension. Submitted in toto, blocks B1-B5.

KEY TO CASSETTES:

- B1-B2 - One lymph node
- B3 - Five lymph nodes
- B4-B5 - Remainder of sample

- C. Received in formalin labeled [redacted] left aortic lymph node" is a fragment of yellow-tan fatty soft tissue, 1.0 grams, 1.0 x 1.0 x 0.5 cm. By palpation, there is one distinct node, pink-tan in color, 1.0 cm in greatest dimension. Submitted in toto, blocks C1-C2.

KEY TO CASSETTES:

- C1 - One lymph node
- C2 - Remainder of sample

[page 3 of 3]
[REDACTED]

Surgical Pathology Report

[REDACTED]

- D. Received in formalin labeled "[REDACTED] right pelvic lymph node" are multiple fragments of soft tan to yellow tissue, 5.0 gms, aggregating up to 3.6 x 3.0 x 1.5 cm. There are six lymph nodes identified, largest up to 1.0 x 0.5 x 0.4 cm (inked blue). Submitted in toto in two cassettes, with six lymph nodes in D1 (largest inked blue) and rest of specimen in D2.
- E. Received in formalin labeled "[REDACTED] right aortic lymph node" is a fragment of yellow-tan fatty soft tissue, 2.0 grams, 3.0 x 2.0 x 0.5 cm. By palpation, there are multiple distinct nodes, pink-tan in color, 0.5 cm in greatest dimension. Submitted in toto, blocks E1-E2.

KEY TO CASSETTES:

E1 - Four lymph nodes
E2 - Remainder of sample

Microscopic Description

The microscopic findings support the above diagnosis.

***Electronically Signed Out [REDACTED]

Source: NCI Genomic Data Commons file 879472f6-38c4-49c7-a922-ecc95b2f7216 (TCGA-BS-A0V6.657466BC-3CA2-4568-BF64-2905571C3666.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).